Gene-level copy-number profile of tumor specimen ALCH-ADBK-TTP1-A from ALCHEMIST case ALCH-ADBK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.3 years (22,018 days).
Specimen ALCH-ADBK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4a7df9ec-63be-44a9-9116-534b66afb96d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADBK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/37e72332-93b4-4185-b2bb-26e286b71b12

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 8,900; copy number 2: 44,387; copy number 3: 4,467; copy number 4: 567.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:2,631,986–2,664,802, 1 gene: TTYH3.
- chr7:7,066,964–7,067,045, 1 gene: MIR3683.
- chr9:21,278,050–27,297,150, 75 genes (broad region; genes not listed).
- chr12:273,954–277,123, 1 gene: AC007406.4.
- chr19:43,211,791–43,269,530, 2 genes: CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,899. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
